Gene-level copy-number profile of tumor specimen TCGA-AA-3542-01A from TCGA case TCGA-AA-3542, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 69.3 years (25,324 days).
Specimen TCGA-AA-3542-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.a5e4c74b-f339-41fc-9685-f74ec2f5775a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AA-3542-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/82e13d7e-f652-4d4b-9f7d-0f34befb7521

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 2: 12,982; copy number 3: 23,001; copy number 4: 19,657; copy number 5: 466; copy number 6: 1,865; copy number 7: 315; copy number 8: 1,309; copy number 9: 208; copy number 10: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AA-3542-01): tumor purity 0.87, ploidy 3.42, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:66,984,103–67,255,195, 6 genes: AC087482.1, HMGN2P47, SMAD3, AC012568.1, AAGAB, RPS24P16.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,842 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:60,046,755–66,432,370, 86 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr8:69,922,751–74,823,313, 92 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr8:76,162,119–91,219,236, 210 genes, copy number 7–10 (broad region; genes not listed).
- chr8:93,134,095–95,948,233, 66 genes, copy number 9 (broad region; genes not listed).
- chr8:97,241,742–103,501,895, 161 genes, copy number 8–9 (broad region; genes not listed).
- chr8:103,559,099–103,769,029, 3 genes, copy number 9: PTMAP15, AC007751.1, AC090686.1.
- chr8:107,899,316–111,040,372, 34 genes, copy number 8 (within-gene range 5–8): RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1, AC104248.1, TRHR, NUDCD1, AC021237.1, ENY2, PKHD1L1, MAPK6P5, EBAG9, SYBU, AC079061.1, AC023245.2, U2, AC023245.1, KCNV1, AC027451.1, RPSAP48, AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47.
- chr8:126,556,323–127,419,050, 1 gene, copy number 8 (within-gene range 6–8): PCAT1.
- chr8:126,671,522–129,683,770, 31 genes, copy number 7–8 (within-gene range 6–8): RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, AC100822.1, LINC00824, CCDC26, AC103833.2, AC103833.1.
- chr8:129,484,057–130,443,674, 19 genes, copy number 7 (within-gene range 6–7): MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1.
- chr8:132,507,962–134,881,899, 48 genes, copy number 7–8: HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1.
- chr13:25,863,250–28,100,592, 54 genes, copy number 7 (within-gene range 6–7): AL157366.1, RN7SL741P, RNY1P3, SHISA2, LINC00415, ATP8A2P3, PRUNEP1, RNF6, AL138966.2, AL138966.1, THAP12P6, CDK8, AL159159.1, AL353789.1, WASF3, RPS3AP44, WASF3-AS1, AL159978.1, GPR12, FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1, USP12-AS1, USP12-AS2, LINC02340, LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1.
- chr20:21,947,647–64,313,132, 1,037 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
